FM case AD16862 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and unspecified parts of biliary tract.
https://portal.gdc.cancer.gov/cases/b0d9856b-48df-47b1-a0a1-ab32d7339236

Male, 69.3 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the biliary tract; metastasis biopsied or resected from the extrahepatic bile duct. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
